CCDI case PBCPXP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/aab1264c-7d3b-4c2e-8605-267782aba2b4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoma in pleomorphic adenoma: ICD-O-3 morphology code: 8941/3; Tissue or organ of origin: Parotid gland; Age at diagnosis: 5.7 years (2,079 days).

Biospecimens (3 samples)
- Sample 0DX7EU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX7F7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX7FS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
